Surgical pathology report (de-identified scan), TCGA case TCGA-14-4157, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Emory University, specimen TCGA-14-4157-01A (Primary Tumor).

[page 1 of 5]
Document Type: AP Report
Document Date: [REDACTED]
Document Status: Modified
Document Title: AP REPORT

*** Final Report ***

SURGICAL PATHOLOGY REPORT

DIAGNOSIS:

1. RIGHT PARIETAL LESION, RESECTION, FS1A, TP1A:
- GLIOBLASTOMA WITH OLIGODENDROGLIOMA COMPONENT, WHO GRADE IV.
2. RIGHT PARIETAL LESION, RESECTION:
- GLIOBLASTOMA WITH OLIGODENDROGLIOMA COMPONENT, WHO GRADE IV.
- SEE COMMENT.

COMMENT:

This high grade glioma shows regions of astrocytic differentiation as well as oligodendroglial differentiation. There is extensive necrosis, including the pseudopalisading type, and abundant microvascular hyperplasia, fulfilling diagnostic criteria for glioblastoma. Immunohistochemistry for p53 shows strong nuclear positivity in nearly every cell. The MIB1 proliferation index is approximately 40%. FISH studies for chromosome 1p are borderline for deletion while FISH for chromosome 19q is positive for deletion. FISH for EGFR is negative for amplification. Studies for chromosome 10q23 (p10) do not show a deletion. The morphologic, immunohistochemical and molecular studies are most consistent with a diagnosis of glioblastoma with oligodendrogloma component, WHO grade IV.

SPECIMEN:

1. Right parietal lesion.
2. Right parietal lesion.

CLINICAL HISTORY/OPERATIVE FINDINGS:

[page 2 of 5]
Right parietal lesion. Symptoms headache, dizziness, weakness.

[REDACTED] 0

GROSS DESCRIPTION:

Two specimens are received, each labeled with the patient's name and medical record number.

Specimen #1 is received fresh for intraoperative consultation and is labeled as "right parietal lesion." The specimen consists of multiple tan hemorrhagic fragments of soft tissue measuring 2.2 x 1.6 x 0.4 cm in aggregate. A touch preparation is performed and representative sections are submitted for intraoperative consultation. The remainder of the cryoblock is transferred to cassette "FS1A." The remainder of the specimen is submitted in cassettes "1B" and "1C." (Dictated by [REDACTED])

Specimen #2 is received in formalin and is labeled as "right parietal lesion." The specimen consists of multiple fragments of soft hemorrhagic tissue measuring in aggregate 3.5 x 2.5 x 0.8 cm. The specimen is submitted entirely, wrapped in lens paper in cassettes "2A" through "2C."

INTRAOPERATIVE CONSULTATION:

FS1A, TP1A: RIGHT PARIETAL LESION, BIOPSY (FROZEN SECTION, TOUCH PREPARATION): HIGH GRADE GLIOMA.

Frozen Section results were communicated to the surgical team and were repeated back by [REDACTED]

Pathologist: [REDACTED]

Page 1 (Continued...)

SURGICAL PATHOLOGY REPORT

MICROSCOPIC DESCRIPTION:

Microscopic examination performed.

SPECIAL STAINS:

KI-67	DONE
P53	DONE

[page 3 of 5]
FISH DONE
FISH DONE
FISH DONE
FISH DONE
FISH DONE
FISH DONE

FLUORESCENCE IN SITU HYBRIDIZATION

SPECIMEN:

Brain, right parietal stem.

CLINICAL HISTORY/REFERRING DIAGNOSIS:

High grade glioma.

GROSS DESCRIPTION:

Paraffin block 2B.

TEST PERFORMED/PROBES USED:

Probe for chromosome 1p36

Probe for chromosome 1q25

Probe for chromosome 19p13

Probe for chromosome 19q13

EGFR gene locus specific probe(7p12)

Chromosome 7 alpha satellite DNA specific probe(7p11.1-7q11.1)

PTEN gene locus specific probe 10q23

Chromosome 10 alpha satellite DNA specific probe (10p11.1-q11.1)

RESULTS:

BORDERLINE POSITIVE for chromosome 1p36 deletion
nuc ish(TP73 x 1), (ANGPTL x 2-4) [27/200]

POSITIVE for chromosome 19q13 deletion
nuc ish(ZNF443 x 2-6), (GLTSCR x 1) [159/200]

NEGATIVE for EGFR gene amplification
nuc ish 7cen(D7Z1x2-10), 7p12(EGFRx2-10) [189/200]

NEGATIVE for chromosome 10q23 deletion
nuc ish(PTEN x 2-6), (D10Z1 x 2-6) [183/200]

Page 2 (Continued...)

FLUORESCENCE IN SITU HYBRIDIZATION

INTERPRETATION:

Fluorescence in situ hybridization was performed using the above listed DNA

[page 4 of 5]
probes [REDACTED]. The probes were simultaneously hybridized to a section of the formalin-fixed paraffin-embedded tissue submitted for evaluation.

Of 200 interphase nuclei analyzed, 13% demonstrated loss of signal for the BORDERLINE 1p36 probe which indicates the presence of deletion for chromosome 1p36. Correlation with clinical and other laboratory parameters is suggested.

Of 200 interphase nuclei analyzed, 30% demonstrated loss of signal for the 19q13 probe which indicates the presence of deletion for chromosome 19q13. Correlation with clinical and other laboratory parameters is suggested.

Of 200 interphase nuclei analyzed, 94% of cells were NEGATIVE for EGFR gene amplification. Positive and negative controls were appropriate. Correlation with clinical and other laboratory parameters is suggested.

Of 200 interphase nuclei analyzed, 92% demonstrated a normal number of signals for the PTEN probe which indicates the absence of deletion for chromosome 10q23. Correlation with clinical and other laboratory parameters is suggested.

[REDACTED]

COMMENT:

The results of this test should not be used alone as the sole basis for diagnosis and/or treatment. These results may, however, prove useful when used in conjunction with other diagnostic procedures and clinical evaluations. Use of these results, in this manner, can be considered to fall within the scope of practice of medicine. This test was developed and its performance characteristics determined by the [REDACTED] Laboratories. It has not been cleared or approved by the U.S. Food and Drug Administration.

Source: NCI Genomic Data Commons file dd307e09-99d5-4324-89c4-102ea86f1c20 (TCGA-14-4157.C8BE1F7B-F0B2-42E0-A6B3-454097F7F003.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).